Somatic mutation profile of tumor specimen MP2PRT-PAPSED-TMP1-A (aliquot MP2PRT-PAPSED-TMP1-A-1-0-D-A83A-36) from MP2PRT case MP2PRT-PAPSED, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.7 years (1,356 days).
Specimen MP2PRT-PAPSED-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a934ad6a-f193-4719-bf30-0a354093024b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPSED-NB1-B (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPSED-NB1-B-1-0-D-A83A-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/41809ba3-6304-4b06-8dcf-eef1ba1c83d4

The open-access MAF lists 20 somatic variants for this specimen: 15 protein-altering or splice-affecting, 3 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 10, Frame Shift Ins 3, Silent 3, Intron 1, In Frame Ins 1, 3'Flank 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GABRB1 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 13/292 reads (4%) | SIFT tolerated (0.5); PolyPhen benign (0.01); catalogued as COSV54970820, COSV54993087; called by muse, mutect2
- PRR12 | c.1630C>T p.R544W (on ENST00000615927; = p.R1365W on NM_020719.3) | Missense Mutation (SNP) | VAF 95/337 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV69816657; called by muse, mutect2, varscan2
- SGCE | c.700G>T p.A234S (on ENST00000647096; = p.A198S on NM_003919.3) | Missense Mutation (SNP) | VAF 38/285 reads (13%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.784); catalogued as rs749526870; called by muse, mutect2, varscan2
- TACC2 | c.113C>T p.T38M | Missense Mutation (SNP) | VAF 76/272 reads (28%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.153); catalogued as rs540521848, COSV57745865; called by muse, varscan2
- AMER1 | c.2902G>A p.V968M | Missense Mutation (SNP) | VAF 151/404 reads (37%) | SIFT tolerated (0.19); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ARHGEF11 | c.2815C>T p.R939C | Missense Mutation (SNP) | VAF 116/303 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BTG1 | c.307_308insTAC p.T103delinsIP | In Frame Ins (INS) | VAF 65/213 reads (31%) | called by mutect2, pindel, varscan2
- CDK13 | c.1151dup p.S385* | Frame Shift Ins (INS) | VAF 138/456 reads (30%) | called by pindel, varscan2
- ERG | c.1100T>G p.M367R (on ENST00000398919 / NM_001243428.1; = p.M343R on NM_004449.4) | Missense Mutation (SNP) | VAF 123/336 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GBP3 | c.1564T>C p.Y522H | Missense Mutation (SNP) | VAF 18/308 reads (6%) | SIFT tolerated (0.73); PolyPhen benign (0.055); called by muse, mutect2
- IGHV1-69 | c.350_351insTGGCACGGAG p.R117Sfs*? | Frame Shift Ins (INS) | VAF 12/46 reads (26%) | called by pindel, varscan2
- RGS19 | c.517_518insGACCGT p.P172_S173ins* | Nonsense Mutation (INS) | VAF 39/328 reads (12%) | called by mutect2, pindel
- SST | c.113C>T p.S38F | Missense Mutation (SNP) | VAF 95/275 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.364); called by muse, mutect2, varscan2
- SUMF1 | c.283C>T p.P95S | Missense Mutation (SNP) | VAF 55/173 reads (32%) | SIFT tolerated (0.09); PolyPhen benign (0.147); called by muse, mutect2, varscan2
- SUSD6 | c.72_73insGG p.L25Gfs*4 | Frame Shift Ins (INS) | VAF 68/238 reads (29%) | called by mutect2, pindel*, varscan2
- DNAH17 | c.2799C>T p.N933= | Silent (SNP) | VAF 106/308 reads (34%) | catalogued as rs377462146; called by muse, mutect2, varscan2
- NALCN | c.3696C>T p.D1232= | Silent (SNP) | VAF 14/269 reads (5%) | catalogued as rs1257172099; called by muse, mutect2
- TSHZ3 | c.189G>A p.P63= | Silent (SNP) | VAF 110/329 reads (33%) | catalogued as rs1335895835; called by muse, mutect2, varscan2
- IGHV1-45 | chr14:106506995 ins TGTGGGGGGCTA | 3'Flank (INS) | VAF 36/106 reads (34%) | called by pindel, varscan2
- LIMCH1 | c.935+7302C>T | Intron (SNP) | VAF 62/202 reads (31%) | catalogued as rs990601885; called by muse, mutect2, varscan2
